Somatic mutation profile of tumor specimen TCGA-IR-A3LF-01A (aliquot TCGA-IR-A3LF-01A-21D-A22X-09) from TCGA case TCGA-IR-A3LF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 64.9 years (23,721 days).
Specimen TCGA-IR-A3LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e62b5dd-587a-4f53-915a-8331dd52d100.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LF-10A (Blood Derived Normal), aliquot TCGA-IR-A3LF-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8df2b2be-f575-4d74-81e7-a2f1e334a430

The open-access MAF lists 119 somatic variants for this specimen: 85 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 32, Nonsense Mutation 9, Intron 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.1978G>C p.G660R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54064939; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2
- AKAP14 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57629397; called by muse, mutect2, varscan2
- AKR1E2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100033392; called by muse, mutect2
- ALDH3A2 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV51565877; called by muse, mutect2, varscan2
- ANKRD55 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV61944719; called by muse, mutect2, varscan2
- ANXA11 | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99626866; called by muse, mutect2
- ATP8B2 | c.749G>A p.W250* (on ENST00000672630; = p.W217* on NM_001005855.2) | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as rs762200945, COSV59245065; called by muse, mutect2
- BICRAL | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV58403915; called by muse, mutect2, varscan2
- BRSK2 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57540808; called by muse, mutect2, varscan2
- BRWD1 | c.5482G>A p.E1828K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV60893387; called by muse, mutect2
- BRWD3 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64744829, COSV64748464; called by muse, mutect2, varscan2
- BUD13 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs766495135, COSV52767325; called by muse, mutect2, varscan2
- C12orf50 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs753291098, COSV53893854, COSV53894105; called by muse, mutect2, varscan2
- CASP2 | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60081535; called by muse, mutect2, varscan2
- CCDC122 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs930201028, COSV71573663; called by muse, mutect2, varscan2
- CCDC88A | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs757163037, COSV55057778; called by muse, mutect2, varscan2
- CCDC88A | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV55057792; called by muse, mutect2, varscan2
- CDC14A | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1477668486, COSV60555895; called by muse, mutect2, varscan2
- CGB1 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.185); catalogued as rs752141739, COSV56819238; called by muse, mutect2, varscan2
- CHRNB2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs771568668, COSV63807821; called by muse, mutect2, varscan2
- CLASP2 | c.3535G>C p.D1179H (on ENST00000359576; = p.D1178H on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56277428; called by muse, mutect2, varscan2
- COP1 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); catalogued as COSV58164022, COSV58179692; called by muse, mutect2, varscan2
- DAP3 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as rs916908988, COSV100546323; called by muse, mutect2
- DHFR2 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs752530039, COSV58934267; called by muse, mutect2, varscan2
- DNAH2 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202126157, COSV50015452; called by muse, mutect2, varscan2
- DOCK1 | c.3419G>C p.R1140T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV54732358; called by muse, mutect2
- DST | c.15404C>G p.S5135* (on ENST00000361203 / NM_001374722.1; = p.S2723* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99751821; called by muse, mutect2
- DYTN | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV71751683; called by muse, mutect2, varscan2
- ENHO | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs578062288, COSV54279239; called by muse, mutect2, varscan2
- ENPP1 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as COSV62930677; called by muse, mutect2, varscan2
- ERAP2 | c.2550C>G p.I850M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs199653916, COSV65938938; called by muse, mutect2
- ERBB2 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); catalogued as COSV54064949; called by muse, mutect2, varscan2
- FOXJ2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV50817616; called by muse, mutect2, varscan2
- GPR173 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV60233750; called by muse, mutect2, varscan2
- GPR174 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52131658; called by muse, mutect2, varscan2
- HCFC2 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV57558126; called by muse, mutect2, varscan2
- HGFAC | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV58749450; called by muse, mutect2, varscan2
- HLA-G | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV64405268; called by muse, mutect2, varscan2
- IGHV3-43 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1409937599; called by muse, mutect2, varscan2
- KCNA1 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs1565433235, COSV66836415; called by muse, mutect2
- KCNK16 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs199507574, COSV100949095; called by muse, mutect2, varscan2
- KIF4A | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV100979411; called by muse, mutect2, varscan2
- KRT86 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs1198164148, COSV99524870; called by muse, mutect2
- MAGEE1 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV100819305; called by muse, mutect2
- MAGEE1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs781944261, COSV63909097; called by muse, mutect2, varscan2
- MAGEE1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs782127481, COSV63909105; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV53796945; called by muse, mutect2
- MPP2 | c.791G>A p.R264Q (on ENST00000461854 / NM_001278372.2; = p.R240Q on NM_005374.5) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs755557995, COSV52233597; called by muse, mutect2, varscan2
- MPZL1 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.342); catalogued as COSV100850322; called by muse, mutect2, varscan2
- MYT1 | c.2988C>A p.D996E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as COSV100114060; called by muse, mutect2
- NEB | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV99415898; called by muse, mutect2
- NINL | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as COSV53999410; called by muse, mutect2
- NUP205 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as rs1373473638, COSV53655863; called by muse, mutect2, varscan2
- OGN | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52760427; called by muse, mutect2, varscan2
- PCDHA7 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs781929038, COSV65342421; called by muse, mutect2, varscan2
- PCDHGB1 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53910531; called by muse, mutect2
- PLB1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as COSV100214894; called by muse, mutect2
- PLCD3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59558858; called by muse, mutect2, varscan2
- PRUNE2 | c.7309C>T p.R2437* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs767797178, COSV65038139; called by muse, mutect2, varscan2
- PTPRN | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180421091; called by muse, mutect2
- RHBDD2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs782231378, COSV99138185; called by muse, mutect2
- SCN7A | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | catalogued as COSV101313103, COSV101313278; called by muse, mutect2
- SDHA | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53766117; called by muse, mutect2, varscan2
- SEMA4B | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV100153227; called by muse, mutect2
- SETD2 | c.4855C>G p.Q1619E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV57456273; called by muse, mutect2, varscan2
- SPATA4 | c.351C>T p.F117= | Splice Region (SNP) | VAF 10/43 reads (23%) | catalogued as rs1405086723, COSV54589036; called by muse, mutect2, varscan2
- STS | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54266478; called by muse, varscan2
- TAF1 | c.2932C>T p.L978F (on ENST00000373790 / NM_138923.4; = p.L999F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334685; called by muse, mutect2, varscan2
- THOP1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV100310403; called by muse, mutect2
- TM4SF5 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.146); catalogued as COSV99564595; called by muse, mutect2
- TP53BP1 | c.2967G>A p.M989I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55497181; called by muse, mutect2, varscan2
- TRRAP | c.8851G>A p.A2951T (on ENST00000359863 / NM_001244580.1; = p.A2933T on NM_003496.3) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.111); catalogued as rs537483764, COSV62840522; called by muse, mutect2, varscan2
- TTC21B | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.466); catalogued as rs1024126846, COSV99691943; called by muse, mutect2, varscan2
- TTC3 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772762977, COSV61286853; called by muse, mutect2, varscan2
- USP6 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51476022, COSV51476667; called by muse, mutect2, varscan2
- VPS8 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99800938; called by muse, mutect2, varscan2
- WDR49 | c.1936G>C p.E646Q (on ENST00000308378 / NM_001366158.1; = p.E987Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57703996, COSV57707588; called by muse, mutect2, varscan2
- ZFHX4 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99257399; called by muse, mutect2
- ZFX | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs758426142, COSV58446740; called by muse, mutect2, varscan2
- BCL6 | c.1833del p.F611Lfs*35 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- CMTM6 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- CUL7 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ILF3 | c.1421G>T p.R474M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ABCA13 | c.11071C>T p.L3691= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101446949, COSV71284322; called by muse, mutect2
- ARHGAP12 | c.276G>A p.T92= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV60966714; called by muse, mutect2, varscan2
- ATAD2 | c.1722G>A p.T574= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs201340625, COSV54885803; called by muse, mutect2, varscan2
- ATP2B3 | c.864C>T p.I288= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV54841902; called by muse, mutect2, varscan2
- BMPR1A | c.1335C>T p.I445= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as rs1218546341, COSV100923346; ClinVar: likely benign; called by muse, mutect2
- BYSL | c.861C>T p.F287= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100026723; called by muse, mutect2, varscan2
- CCNL2 | c.1356C>T p.C452= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV68766179; called by muse, mutect2
- CCNP | c.207G>C p.L69= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55687285; called by muse, mutect2
- CHD2 | c.2376G>A p.K792= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV67707179; called by muse, mutect2, varscan2
- DHX16 | c.795C>T p.H265= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs201025174, COSV64563275; called by muse, mutect2, varscan2
- DLX3 | c.156G>T p.S52= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV71547525; called by muse, mutect2, varscan2
- DST | c.15495C>T p.F5165= (on ENST00000361203 / NM_001374722.1; = p.F2753= on NM_015548.5) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV55001263; called by muse, mutect2
- FAM153B | c.672C>T p.I224= (on ENST00000253490; = p.I147= on NM_001265615.1) | Silent (SNP) | VAF 22/369 reads (6%) | catalogued as COSV99498802, COSV99498995; called by muse, mutect2
- FCF1 | c.204C>T p.H68= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58696250; called by muse, mutect2, varscan2
- GTF2I | c.360C>T p.F120= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV60399839; called by muse, mutect2, varscan2
- HADHA | c.1113G>C p.L371= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV101023771; called by muse, mutect2
- INSL3 | c.351C>T p.L117= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV57952880; called by muse, mutect2, varscan2
- ITGAX | c.414C>T p.L138= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV51642481; called by muse, mutect2, varscan2
- JPH3 | c.864C>T p.Y288= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs565470642, COSV52465046; called by muse, mutect2, varscan2
- KIF21B | c.442C>T p.L148= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV59753440; called by muse, mutect2, varscan2
- KLF17 | c.1089G>A p.K363= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV64855978; called by muse, mutect2
- KLRC1 | c.213C>A p.L71= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV61724899; called by muse, mutect2
- LMTK3 | c.84C>T p.F28= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1201301822, COSV54310270; called by muse, mutect2, varscan2
- NSF | c.1983C>T p.F661= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs562007080, COSV99833695; called by muse, mutect2, varscan2
- PLXNC1 | c.1608G>A p.V536= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99312537; called by muse, mutect2
- RGS7BP | c.15G>A p.P5= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV61833788; called by muse, mutect2
- RIMS1 | c.3474G>A p.E1158= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV53443236; called by muse, mutect2
- SETX | c.2283G>A p.S761= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs370328795; called by muse, mutect2, varscan2
- SLC17A6 | c.255C>T p.F85= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV54134123; called by muse, mutect2, varscan2
- SMPD2 | c.1035G>A p.A345= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as rs938647728; called by muse, mutect2
- VSIG2 | c.834T>C p.Y278= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs773786109, COSV52517972; called by muse, mutect2, varscan2
- ZNF69 | c.156G>C p.V52= (on ENST00000429654 / NM_001364730.1; = p.V38= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV60903009; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23459G>A | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100529695, COSV59387663; called by muse, mutect2
- USH1C | c.1646+1106G>A | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as COSV50014458; called by muse, mutect2
